Somatic mutation profile of tumor specimen 0DAWAI from CCDI case PBBKHM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 13.6 years (4,962 days).
Specimen 0DAWAI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab0e6a37-db87-46ce-a066-cd8151d33e0e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAWAE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc146b1f-0e0b-4fbc-88c2-c5d4e92aa451

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STRIP2 | c.1256C>T p.P419L | Missense Mutation (SNP) | VAF 20/599 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); called by muse, mutect2
- SCRN2 | c.204G>A p.S68= | Silent (SNP) | VAF 91/722 reads (13%) | catalogued as rs1452870624; called by muse, mutect2, varscan2
